National Lung Screening Trial (NLST) participant 109189 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 61 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, display field of view 46 cm, reconstruction filter Siemens, other.
- T1: No screening result: Not Expected - Cancer before screening window.
- T2: No screening result: Not Expected - Cancer before screening window.

Abnormalities recorded by the reading radiologist on the CT screens (4 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 231.
- T0 abnormality 2: Atelectasis, segmental or greater.
- T0 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 4 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 241.
- T0 abnormality 4: Other minor abnormality noted.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T0; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 47, study year T0. Site: middle lobe of lung (ICD-O-3 C34.2). Primary tumour location: right middle lobe, right hilum. Histology: squamous cell carcinoma, NOS (ICD-O-3 8070/3). Cancer type as recorded on the NLST diagnostic evaluation form (the trial's best information on type): basaloid squamous cell carcinoma (ICD-O-3 8083). Grade: poorly differentiated (G3). ICD-O-3 grade: moderately differentiated, grade II. Tumour size on pathology: 95 mm. AJCC 6th edition staging: stage IIB (best stage, from pathologic TNM); clinical T2 N0 M0 (stage IB); pathologic T3 N0 M0 (stage IIB). AJCC 7th edition staging: stage IIB; clinical T2a N0 M0; pathologic T3 N0 M0.
